Somatic mutation profile of tumor specimen TARGET-40-PASEFS-01A (aliquot TARGET-40-PASEFS-01A-01D) from TARGET case TARGET-40-PASEFS, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 18.1 years (6,625 days).
Specimen TARGET-40-PASEFS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 56d7c17e-4046-4e8f-a845-a4c5fee02dff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-PASEFS-10A (Blood Derived Normal), aliquot TARGET-40-PASEFS-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9f4a274b-ceb0-4804-a129-5f63aa4fd29a

The open-access MAF lists 65 somatic variants for this specimen: 30 protein-altering or splice-affecting, 13 silent, 22 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 13, Intron 9, RNA 7, 3'UTR 4, Splice Site 2, Frame Shift Del 2, 5'Flank 1, Nonsense Mutation 1, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.991C>T p.Q331* | Nonsense Mutation (SNP) | VAF 107/108 reads (99%) | hotspot (GDC flag); catalogued as CM1511153, COSV52664188; called by muse, mutect2, varscan2
- ADH1A | c.121-1G>C p.X41_splice | Splice Site (SNP) | VAF 84/268 reads (31%) | catalogued as COSV52924982; called by muse, mutect2, varscan2
- AGA | c.210C>G p.D70E | Missense Mutation (SNP) | VAF 76/247 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as COSV99219655; called by muse, mutect2, varscan2
- ATM | c.6109G>A p.E2037K | Missense Mutation (SNP) | VAF 13/131 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as rs1448711296, COSV53723692; called by muse, mutect2
- CCDC9 | c.1031G>A p.R344H | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as rs778362376; called by muse, mutect2, varscan2
- CRISP3 | c.344A>C p.H115P (on ENST00000371159 / NM_001368123.1; = p.H97P on NM_006061.4) | Missense Mutation (SNP) | VAF 147/156 reads (94%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs1315423830; called by muse, mutect2, varscan2
- CXXC1 | c.1729G>A p.G577S | Missense Mutation (SNP) | VAF 43/59 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as COSV99496930; called by muse, mutect2, varscan2
- DNAH11 | c.5594G>A p.R1865Q | Missense Mutation (SNP) | VAF 57/370 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs749869317; called by muse, mutect2, varscan2
- E2F8 | c.2137G>A p.G713R | Missense Mutation (SNP) | VAF 161/172 reads (94%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.657); catalogued as rs754334957, COSV100001551, COSV51463335; called by muse, mutect2, varscan2
- FAM187B | c.988G>A p.V330M | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as rs1365152948; called by muse, mutect2, varscan2
- HCN3 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 60/198 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as rs1400765034; called by muse, varscan2
- MAP3K1 | c.2266G>T p.G756C | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68126527; called by muse, mutect2
- MYCN | c.1196C>T p.S399F | Missense Mutation (SNP) | VAF 41/205 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs1057520637, COSV55260415; ClinVar: likely benign; called by muse, mutect2, varscan2
- NEK3 | c.333G>A p.M111I | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.62); PolyPhen benign (0.006); catalogued as rs762371412; called by muse, mutect2, varscan2
- OR5I1 | c.767C>T p.T256I | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.455); catalogued as rs939426473, COSV56886059; called by muse, mutect2, varscan2
- PCDHGA11 | c.1087C>G p.P363A | Missense Mutation (SNP) | VAF 43/206 reads (21%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.02); catalogued as rs1207977453; called by muse, mutect2, varscan2
- PLA2R1 | c.1834+1G>T p.X612_splice | Splice Site (SNP) | VAF 12/132 reads (9%) | catalogued as rs775745800; called by muse, mutect2
- PLCG1 | c.481T>G p.F161V | Missense Mutation (SNP) | VAF 22/223 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV54816080; called by muse, mutect2, varscan2
- POLK | c.2279G>A p.R760K | Missense Mutation (SNP) | VAF 13/144 reads (9%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as rs1202101697; called by muse, mutect2
- SMCHD1 | c.3826G>C p.D1276H | Missense Mutation (SNP) | VAF 45/165 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV55267413; called by muse, mutect2, varscan2
- AGK | c.215G>T p.C72F | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); called by muse, mutect2
- ATRX | c.2154dup p.S719Ifs*2 | Frame Shift Ins (INS) | VAF 157/223 reads (70%) | called by mutect2, pindel, varscan2
- BCHE | c.800C>G p.A267G | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.119); called by muse, mutect2
- EMC3 | c.318G>T p.M106I | Missense Mutation (SNP) | VAF 80/164 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- KCNH4 | c.1061A>T p.Y354F | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, varscan2
- PABPC5 | c.806T>A p.L269H | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- PSME4 | c.4693G>C p.D1565H | Missense Mutation (SNP) | VAF 31/179 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- SP140 | c.2202_2205del p.M735Rfs*26 | Frame Shift Del (DEL) | VAF 18/46 reads (39%) | called by mutect2, varscan2
- SSC4D | c.964_973del p.Q322Gfs*96 | Frame Shift Del (DEL) | VAF 2/16 reads (13%) | called by mutect2, varscan2
- SSTR3 | c.547G>A p.G183R | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- AXL | c.2211G>A p.V737= (on ENST00000301178 / NM_021913.5; = p.V728= on NM_001699.6) | Silent (SNP) | VAF 28/153 reads (18%) | called by muse, mutect2, varscan2
- FAM135B | c.4158G>T p.V1386= | Silent (SNP) | VAF 38/582 reads (7%) | called by muse, mutect2
- FAM160A1 | c.18G>A p.S6= | Silent (SNP) | VAF 7/137 reads (5%) | catalogued as rs1040393362; called by muse, mutect2
- HCN3 | c.576G>A p.L192= | Silent (SNP) | VAF 44/151 reads (29%) | called by muse, varscan2
- LRP2 | c.9555A>G p.E3185= | Silent (SNP) | VAF 25/219 reads (11%) | called by muse, mutect2, varscan2
- LRRC8A | c.1152G>A p.P384= | Silent (SNP) | VAF 52/115 reads (45%) | catalogued as rs980321768, COSV99396312; called by muse, mutect2, varscan2
- MOCOS | c.2190C>G p.T730= | Silent (SNP) | VAF 19/102 reads (19%) | catalogued as rs1325922482; called by muse, mutect2, varscan2
- OR51S1 | c.27C>A p.A9= | Silent (SNP) | VAF 42/176 reads (24%) | catalogued as rs781506849; called by muse, mutect2, varscan2
- OR5AU1 | c.507C>T p.C169= | Silent (SNP) | VAF 65/233 reads (28%) | catalogued as rs752998740, COSV58615554; called by muse, mutect2, varscan2
- PREB | c.978C>T p.I326= | Silent (SNP) | VAF 102/523 reads (20%) | catalogued as COSV53206019; called by muse, mutect2, varscan2
- SUGCT | c.876C>G p.A292= | Silent (SNP) | VAF 69/125 reads (55%) | called by muse, mutect2, varscan2
- SYT16 | c.1050G>A p.K350= | Silent (SNP) | VAF 24/110 reads (22%) | catalogued as rs1352458170, COSV101413536; called by muse, mutect2, varscan2
- ZNF234 | c.1077T>C p.F359= | Silent (SNP) | VAF 16/188 reads (9%) | called by muse, mutect2
- AC092821.1 | n.7285C>G | RNA (SNP) | VAF 4/95 reads (4%) | catalogued as rs3829323; called by muse, mutect2
- AL137028.1 | n.368A>C | RNA (SNP) | VAF 10/24 reads (42%) | called by muse, mutect2
- ALMS1P1 | n.1043-9588G>A | Intron (SNP) | VAF 16/48 reads (33%) | catalogued as rs368610477; called by muse, varscan2
- ARHGEF4 | chr2:130916064 G>T | 5'Flank (SNP) | VAF 18/19 reads (95%) | called by muse, mutect2, varscan2
- CCNQP1 | n.139G>A | RNA (SNP) | VAF 73/176 reads (41%) | catalogued as rs1391135826; called by muse, mutect2, varscan2
- CRTAM | c.*37C>A | 3'UTR (SNP) | VAF 32/80 reads (40%) | called by muse, varscan2
- CRTC2 | c.997+95C>T | Intron (SNP) | VAF 36/106 reads (34%) | called by muse, mutect2, varscan2
- CRTC2 | c.608-58C>G | Intron (SNP) | VAF 62/212 reads (29%) | called by muse, mutect2, varscan2
- CST8 | c.-62C>A | 5'UTR (SNP) | VAF 10/126 reads (8%) | called by muse, mutect2
- DEFB108D | n.173C>T | RNA (SNP) | VAF 23/135 reads (17%) | called by muse, mutect2, varscan2
- FIG4 | c.2546+67del | Intron (DEL) | VAF 58/62 reads (94%) | called by mutect2, varscan2
- GP6 | c.35-58A>T | Intron (SNP) | VAF 20/21 reads (95%) | called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85953A>C | Intron (SNP) | VAF 61/280 reads (22%) | called by muse, mutect2, varscan2
- MDGA2 | c.2593+25T>C | Intron (SNP) | VAF 20/122 reads (16%) | called by muse, mutect2, varscan2
- OR7E13P | n.85T>A | RNA (SNP) | VAF 19/114 reads (17%) | called by muse, mutect2, varscan2
- PDE1C | c.*107C>A | 3'UTR (SNP) | VAF 20/249 reads (8%) | called by muse, mutect2
- PKM | c.378+118G>T | Intron (SNP) | VAF 60/105 reads (57%) | called by muse, mutect2, varscan2
- RPL7P47 | n.147C>A | RNA (SNP) | VAF 64/279 reads (23%) | called by muse, mutect2, varscan2
- SCART1 | c.683-178C>G | Intron (SNP) | VAF 3/33 reads (9%) | catalogued as rs1293064154; called by muse, mutect2, varscan2
- TRPM5 | c.*22G>A | 3'UTR (SNP) | VAF 23/58 reads (40%) | called by muse, mutect2, varscan2
- TTYH3 | c.*110C>G | 3'UTR (SNP) | VAF 6/15 reads (40%) | called by muse, mutect2, varscan2
- WHSC1L2P | n.403C>T | RNA (SNP) | VAF 21/137 reads (15%) | called by muse, mutect2, varscan2
